Somatic mutation profile of tumor specimen TCGA-DU-8164-01A (aliquot TCGA-DU-8164-01A-11D-2253-08) from TCGA case TCGA-DU-8164, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 51.3 years (18,735 days).
Specimen TCGA-DU-8164-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f4a9be8-8e38-4ac8-b625-106b79d46858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8164-10A (Blood Derived Normal), aliquot TCGA-DU-8164-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ba3fc99-38db-4469-a766-42a68ae21e8d

The open-access MAF lists 27 somatic variants for this specimen: 25 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 23, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSK | c.689G>T p.W230L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66169395; called by muse, mutect2, varscan2
- ATP8B4 | c.2596T>G p.Y866D | Missense Mutation (SNP) | VAF 108/233 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV52712019; called by muse, mutect2, varscan2
- CACNA1E | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62387281; called by muse, mutect2
- DCC | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568363997, CD152817, COSV100503918, COSV59093942; called by muse, mutect2, varscan2
- ERICH3 | c.2542G>T p.V848F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV58602892; called by muse, mutect2, varscan2
- FANCC | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV56658871; called by muse, mutect2, varscan2
- FEM1A | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54163312; called by muse, mutect2, varscan2
- FUBP1 | c.501del p.I167Mfs*25 | Frame Shift Del (DEL) | VAF 47/67 reads (70%) | catalogued as COSV53939715; called by mutect2, pindel, varscan2
- HOXB8 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53310183; called by muse, mutect2, varscan2
- KXD1 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs200331878; called by muse, mutect2, varscan2
- LRFN2 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248393139, COSV57825464; called by muse, mutect2, varscan2
- NUP210L | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as rs771522844, COSV55141015; called by muse, mutect2, varscan2
- OR4D10 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV73259995, COSV73260033; called by muse, mutect2
- PDGFC | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56847047; called by muse, mutect2
- PTCD1 | c.1633G>T p.V545F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV52862345; called by muse, mutect2, varscan2
- RGS6 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59570302; called by muse, mutect2, varscan2
- SCUBE3 | c.1002C>G p.N334K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51455777; called by muse, mutect2
- SETD2 | c.4687G>C p.G1563R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57434132, COSV57452998; called by muse, mutect2, varscan2
- SOWAHB | c.982T>G p.W328G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57554229; called by muse, mutect2, varscan2
- TENM2 | c.6760A>G p.I2254V (on ENST00000518659 / NM_001122679.2; = p.I2015V on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV69126815; called by muse, mutect2, varscan2
- TTN | c.70232G>A p.R23411H (on ENST00000591111; = p.R15987H on NM_003319.4) | Missense Mutation (SNP) | VAF 97/242 reads (40%) | PolyPhen probably damaging (0.917); catalogued as rs542720402, COSV59961982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF688 | c.553T>A p.C185S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56300261; called by muse, mutect2, varscan2
- MTA1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- JCHAIN | c.144C>T p.S48= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as rs748563018, COSV54658374; called by muse, mutect2, varscan2
- PTPRO | c.675T>C p.P225= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs768626845, COSV55506244; called by muse, mutect2, varscan2
